Gene-level copy-number profile of tumor specimen TCGA-XU-A931-01A from TCGA case TCGA-XU-A931, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 61.4 years (22,432 days).
Specimen TCGA-XU-A931-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.43988b6f-5383-41da-b759-30f7c88cc189.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XU-A931-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed6dc826-7891-43eb-8cec-1d52d8e5b746

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,300; copy number 4: 40,606; copy number 5: 2,985; copy number 6: 7,625; copy number 9: 4,304.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XU-A931-01A-11D-A422-01): tumor purity 0.65, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,403 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:108,927,361–248,919,946, 2,946 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr15:82,925,884–101,933,350, 457 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
